Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8182, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8182-01A (Primary Tumor).

[page 1 of 7]
Surgical Pathology Report

--- Clinical History ---

Neoplasm of unspecified nature of brain [239.6].

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

- A. Left frontal tumor, biopsy: ✓
- Oligodendroglioma (WHO grade II)
- B. Left frontal tumor, excision: ✓
- Oligodendroglioma (WHO grade II)

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the Immunohistochemistry and Histology Core Facility laboratories in the Department of Pathology at the and are not required to have nor do they have FDA approval.

---Addendum Report---

Addendum

Status:

[page 2 of 7]
Detection of 1p36 and 19q by LSI 1p36/LSI 1q25 and LSI 19q13/19p13
Dual-Color Probe Sets
Pathology Core Facility, Molecular Diagnostic Laboratory
Department of Pathology and Laboratory Medicine

Case No _____ Outside Case#: _____
Pathologist _____ Patient Name: _____

Source of case _____ Patient MRN: _____
Block used B3
Tissue fixation formalin-fixed tissue
Tissue source Brain

RESULTS

Ratio of 0.81 Cell count of 1p/1q: 110
Ratio of 0.85 Cell count of 19q/19p: 127

Interpretation of Results: A) 1p no loss; B) 19q no loss

Interpretation of findings:

A) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 1q25 signals and 2 to 3 chromosome 1p36 signals (locus of interest), and the ratio of 1p36/1q25 Ratio was >0.8 . The results are consistent with no loss of the 1p36 locus of interest.

B) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 19p13 signals and 2 to 3 chromosome 19q13 signals (locus of interest), and the ratio of 19q13/19p13 Ratio was >0.8 . The results are consistent with no loss of the 19q13 locus of interest.

Number of Observers: ?

Test Interpreted By: _____

Comments

The resultant FISH section/slide is scanned by a trained licensed medical technologist and analyzed using a FDA-approved, validated semi-automated scanning imaging

workstation (Duet) and accompanying imaging analysis software (BioView). The resultant FISH section/slide is then presented to the interpreting Pathologist, who will

reviews the FISH results from BioView and compares them to the results manually observed under an Olympus Fluorescence Microscope. Therefore the ratio is enumerated

by computer-aided counting (BioView) as well as manual counting.

Interpretation of Test

The ratio for probe set 1 is derived by dividing the total number of LSI 1p36 signals by the total number of LSI 1q25 signals in at least 20 interphase nuclei with

nonoverlapping nuclei in the neoplastic glial cells. Cells with no signals or with signals of only one color are disregarded. The ratio for probe set 2 is derived by dividing the

total number of LSI 19q13 signals by the total number of LSI 19p13 signals in at least 2 sets of 20 interphase nuclei with nonoverlapping nuclei in the neoplastic glial cells at

two different areas of the sample. Cells with no signals or with signals of only one color are disregarded. References ranges for our laboratory for allelic loss versus no

allelic loss were established by evaluating both probe sets in a series of 40 normal cases from 10 different organs. For both probe set 1 and 2 a ratio of less than 0.80 taken

from at least 2 sets of 20 interphase nuclei at 2 different areas with

[page 3 of 7]
nonoverlapping nuclei is consistent with allelic loss. FISH and H&E stained slides have been reviewed

by the interpreting pathologist.

Limitations

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and

their performance characteristics determined by the Pathology Core Facility of the They have not been cleared by the US Food and

Drug Administration. The FDA has determined that such clearance or approval is not necessary.

---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Left frontal tumor (Frozen section performed):

- Infiltrating glial neoplasm.

Note: Reported t

Examining pathologist

---MICROSCOPIC:---

Sections reveal an infiltrating moderately cellular neoplasm composed of glial elements having round to ovoid nuclei and scant cytoplasm. Many cells display perinuclear clearings. In areas, nuclear pleomorphism, mini-gemistocytes and infrequent mitotic figures are identified. Immunostain for GFAP is positive in some tumor cells as well as background reactive astrocytes. A ki-67 stain shows a proliferation index of about 3-4%, by manual quantification.

---SPECIMEN(S) RECEIVED:---

NBX

A: Neuropath, Brain, Bx

B: Neuropath, Brain, Bx

---GROSS DESCRIPTION:---

The specimens are received in two properly labeled containers with the patient's name and accession number, one of which is submitted for frozen section.

A. The specimen is designated "left frontal tumor" and consists of a 0.9 x 0.4 x 0.2 cm aggregate of pink and gray tissue. A touch prep is prepared and the specimen is entirely submitted for frozen section, transferred cassette AF1.

[page 4 of 7]
B. The specimen is designated "left frontal tumor" and consists of a 4.1 x 2.2 x 0.6 cm aggregate of tan and gray glistening, extremely soft tissue with accompanying blood clot. The specimen is entirely submitted in cassette B1-B3 with the smallest portions of tissue submitted in a filter bag, cassette B1 and largest portion of tissue sectioned and included in cassette B3. [REDACTED]

[page 5 of 7]
Surgical Pathology Report

--- Clinical History ---

Neoplasm of unspecified nature of brain [239.6].

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

- A. Left frontal tumor, biopsy: ✓
- Oligodendroglioma (WHO grade II)
- B. Left frontal tumor, excision: ✓
- Oligodendroglioma (WHO grade II)

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the Immunohistochemistry and Histology Core Facility laboratories in the Department of Pathology at the and are not required to have nor do they have FDA approval.

---Addendum Report---

Addendum

Status:

[page 6 of 7]
Detection of 1p36 and 19q by LSI 1p36/LSI 1q25 and LSI 19q13/19p13
Dual-Color Probe Sets
Pathology Core Facility, Molecular Diagnostic Laboratory
Department of Pathology and Laboratory Medicine

Case No Outside Case#:
Pathologist Patient Name:
Source of case Patient MRN:
Block used B3
Tissue fixation formalin-fixed tissue
Tissue source Brain

RESULTS

Ratio of 0.81 Cell count of 1p/1q: 110
Ratio of 0.85 Cell count of 19q/19p: 127

Interpretation of Results: A) 1p no loss; B) 19q no loss

Interpretation of findings:

A) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 1q25 signals and 2 to 3 chromosome 1p36 signals (locus of interest), and the ratio of 1p36/1q25 Ratio was >0.8 . The results are consistent with no loss of the 1p36 locus of interest.

B) (negative) The majority of tumors cells displayed 2 to 3 control chromosome 19p13 signals and 2 to 3 chromosome 19q13 signals (locus of interest), and the ratio of 19q13/19p13 Ratio was >0.8 . The results are consistent with no loss of the 19q13 locus of interest.

Number of Observers: 2

Test Interpreted By:

Comments

The resultant FISH section/slide is scanned by a trained licensed medical technologist and analyzed using a FDA-approved, validated semi-automated scanning

workstation (Duet) and accompanying imaging analysis software (BioView). The resultant FISH section/slide is then presented to the interpreting Pathologist, who will

reviews the FISH results from BioView and compares them to the results manually observed under an Olympus Fluorescence Microscope. Therefore the ratio is enumerated

by computer-aided counting (BioView) as well as manual counting.

Interpretation of Test

The ratio for probe set 1 is derived by dividing the total number of LSI 1p36 signals by the total number of LSI 1q25 signals in at least 20 interphase nuclei with

nonoverlapping nuclei in the neoplastic glial cells. Cells with no signals or with signals of only one color are disregarded. The ratio for probe set 2 is derived by dividing the

total number of LSI 19q13 signals by the total number of LSI 19p13 signals in at least 2 sets of 20 interphase nuclei with nonoverlapping nuclei in the neoplastic glial cells at

two different areas of the sample. Cells with no signals or with signals of only one color are disregarded. References ranges for our laboratory for allelic loss versus no

allelic loss were established by evaluating both probe sets in a series of 40 normal cases from 10 different organs. For both probe set 1 and 2 a ratio of less than 0.80 taken

from at least 2 sets of 20 interphase nuclei at 2 different areas with

[page 7 of 7]
B. The specimen is designated "left frontal tumor" and consists of a 4.1 x 2.2 x 0.6 cm aggregate of tan and gray glistening, extremely soft tissue with accompanying blood clot. The specimen is entirely submitted in cassette B1-B3 with the smallest portions of tissue submitted in a filter bag, cassette B1 and largest portion of tissue sectioned and included in cassette B3. [REDACTED]

Source: NCI Genomic Data Commons file ca5c57dd-ea17-41de-b2a3-3265f7b6bbf0 (TCGA-FG-8182.E5BE5E58-2293-4328-A626-08E497FE6F33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).